Surgical pathology report (de-identified scan), TCGA case TCGA-AL-7173, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AL-7173-01A (Primary Tumor).

[page 1 of 2]
Sex: F

Source of Specimen(s):

- 1: Para caval Lymph Node
- 2: Right Kidney, resection
- 3: Para caval Lymph Node
- 4: Peri renal fat

Gross Description:

Received in four parts.

Source of tissue: 1. Labeled #1, "paracaval lymph node"

Intraoperative Consultation: NO TUMOR SEEN PER [REDACTED] (VERIFIED).

Gross Description: Received fresh for frozen section diagnosis labeled
", paracaval lymph node" is a 1.8 x 1.1 x 0.6

cm brownish-tan firm rounded lymph node. Submitted entirely for frozen
section as IFSA.

Source of tissue: 2. Labeled #2, "right kidney"

Gross Description: Received fresh labeled ",
right kidney" is a 273 gram/13 x 7 x 5 cm kidney partially covered by
retracted perinephric fat. Upon sectioning, obliterating approximately
two-thirds of the kidney by volume located within the mid/inferior pole is
a 8.5 x 5.5 x 5.0 cm hemorrhagic golden orangish-tan partially necrotic,
encapsulated rounded tumor mass. Along the outer surface vantage point
this mass appears very unevenly lobulated, and some points appear to
extend through the capsule to the inked outer surface. Also, this
impinging mass significant reduces the volume of the pelvocaliceal
collecting system, and the remaining viewable pelvic mucosa appears
pale-tan and glistening. The outer superior pole kidney surface is
lobulated, and this somewhat normal appearing renal parenchyma has
somewhat demarcated corticomedullary borders with a cortex thickness of
0.9 cm. Upon opening, the 13.5 x 0.5 cm uninvolved ureter has an
unremarkable mucosal surface, and a very short vein segment is probed
closely along, but uninvolved by a tumor edge.

Within the hilar fat are three pale grayish white hard rounded metastatic
appearing lymph nodes ranging in size 0.4-0.9 cm, and within the superior
pole fat is a 0.9 cm hemorrhagic firmness for probable lymph node, and no
obvious adrenal gland. Representative sections9.

Designation of Sections: 2A vascular and ureteral margins. 2B/2C
capsule invasion?, and tumor in relation to normal kidney. 2D additional
tumor along outer surface. 2E/2F tumor in relation to pelvic mucosa. 2G
tumor in relation to vein. 2H superior pole. 2I lymph nodes.

Source of tissue: 3. Labeled #3, "paracaval lymph node"

[page 2 of 2]
Gross Description: Received fresh labeled "paracaval lymph node" is an 8 x 1.5 x 0.5 cm portion of soft lobulated fat containing four potential lymph nodes ranging in size 0.2-1.9 cm. The largest lymph node is color-coded by the application of black ink prior to sectioning. Entirely submitted in 3A.

Source of tissue: 4. Labeled #4, "fat around kidney"

Gross Description: Received fresh labeled "fat around kidney" is a 6.5 x 5.5 x 0.4 cm portion of partially hemorrhagic soft lobulated fat. Upon palpation, the 0.3 x 0.2 cm firm focus is designated by the application of black ink. Otherwise, there are no other obvious findings. Representative sections1.

Final Diagnosis:

1. Paracaval lymph node, excision:

- No tumor seen in one lymph node, (0/1).

2. Right kidney, nephrectomy:

- Papillary renal cell carcinoma type 2, 8.5 cm, involving renal sinus and perinephric fat.

- Surgical resection margins are free of carcinoma.

- Metastatic papillary renal cell carcinoma involving four of five hilar lymph nodes, (4/5).

- Extracapsular extension is identified.

3. Paracaval lymph nodes, excision:

- No tumor seen in eight lymph nodes, (0/8).

4. Fat around kidney, excision:

- Benign adipose tissue.

pTNM: T3 N2 Mx

Source: NCI Genomic Data Commons file 1415daa7-2a7c-4306-bc40-2f36b7133329 (TCGA-AL-7173.9E0E28E8-E4FD-47B3-8BC0-76FB43742C1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).